Somatic mutation profile of tumor specimen ALCH-B05Q-TTP1-A (aliquot ALCH-B05Q-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B05Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.5 years (24,271 days).
Specimen ALCH-B05Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aad550a8-a773-456d-86b6-c3c21332437d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B05Q-NB1-A (Blood Derived Normal), aliquot ALCH-B05Q-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41d9941f-eb22-4d30-b146-339fffee9d0c

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Nonsense Mutation 3, Silent 3, Splice Site 2, Intron 2, Frame Shift Del 2, RNA 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 407/1433 reads (28%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by mutect2, pindel, varscan2
- MEGF10 | c.3166C>T p.R1056* | Nonsense Mutation (SNP) | VAF 154/735 reads (21%) | catalogued as rs989552169, COSV57245634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 131/620 reads (21%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM9 | c.1962+2T>C p.X654_splice | Splice Site (SNP) | VAF 46/906 reads (5%) | catalogued as COSV101166178; called by muse, mutect2
- AMIGO1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63990626; called by muse, mutect2, varscan2
- CCNE1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs749045990, COSV52903896; called by muse, mutect2
- CCNT2 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 27/479 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51474706; called by muse, mutect2
- FAT2 | c.8033G>A p.R2678Q | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs373844920, COSV55813031; called by muse, mutect2
- HMCN2 | c.2113G>A p.V705M | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1406494567; called by muse, mutect2
- KLK7 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as COSV58344164; called by muse, mutect2
- OR4E2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs771078421, COSV57731482; called by muse, mutect2, varscan2
- PCDHB9 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 38/514 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53375191, COSV53379472; called by muse, mutect2
- PRNP | c.730A>T p.I244F | Missense Mutation (SNP) | VAF 103/361 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV65173788; called by muse, mutect2, varscan2
- PTGIS | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 158/910 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs144816768; called by muse, mutect2, varscan2
- SLC39A4 | c.1399G>A p.E467K (on ENST00000301305 / NM_001374839.1; = p.E442K on NM_017767.3) | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as COSV52778526; called by muse, mutect2, varscan2
- ANAPC1 | c.3652G>A p.G1218S | Missense Mutation (SNP) | VAF 113/878 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD62 | c.1714A>T p.R572W | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- CDH12 | c.1449T>A p.N483K | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CPD | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- DTNA | c.877-1G>A p.X293_splice | Splice Site (SNP) | VAF 81/769 reads (11%) | called by muse, mutect2, varscan2
- FMN2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- GOLGA6L7 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAQR5 | c.849_850del p.L284Gfs*43 | Frame Shift Del (DEL) | VAF 81/766 reads (11%) | called by mutect2, pindel, varscan2
- PIGZ | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); called by mutect2, varscan2
- RABL2A | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 58/449 reads (13%) | called by muse, mutect2, varscan2
- RPL36AL | c.33_37del p.F11Lfs*15 | Frame Shift Del (DEL) | VAF 48/217 reads (22%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 56/1274 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2
- SPANXC | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SPTBN2 | c.4378G>A p.E1460K | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.241); called by muse, mutect2
- TRIM9 | c.1525T>C p.Y509H | Missense Mutation (SNP) | VAF 42/550 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKDD1A | c.342G>A p.G114= | Silent (SNP) | VAF 34/443 reads (8%) | called by muse, mutect2
- KIAA1549L | c.1971A>T p.A657= (on ENST00000321505; = p.A954= on NM_012194.3) | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- TIMM44 | c.852C>T p.T284= | Silent (SNP) | VAF 32/448 reads (7%) | catalogued as rs766405927; called by muse, mutect2
- AC136628.2 | n.1046G>A | RNA (SNP) | VAF 57/358 reads (16%) | called by muse, mutect2, varscan2
- IKBKB | c.105+44C>T | Intron (SNP) | VAF 29/279 reads (10%) | catalogued as rs767029411; called by muse, mutect2, varscan2
- MYADM | chr19:53874325 A>G | 3'Flank (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- TXNDC8 | c.255+2193C>T | Intron (SNP) | VAF 28/378 reads (7%) | called by muse, mutect2
